Somatic mutation profile of tumor specimen 0DXAR2 from CCDI case PBCRIE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,208 days).
Specimen 0DXAR2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b82826cc-13e8-46a7-acd0-a445ef892c0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXAQI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d497802-cb79-4b0f-9679-d08b2b18deee

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919_1921del p.V640_K641delinsE (on ENST00000288602 / NM_001374244.1; = p.V600_K601delinsE on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 70/348 reads (20%) | catalogued as rs397516897, COSV56060025; ClinVar: likely pathogenic; called by mutect2, varscan2
- CCDC38 | c.1154T>C p.I385T | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.655); catalogued as rs149118920; called by muse, mutect2, varscan2
- GCM1 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1196903120; called by muse, mutect2
- ZNF696 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs749462125; called by muse, mutect2, varscan2
- SUPT6H | c.2529G>T p.K843N | Missense Mutation (SNP) | VAF 11/375 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); called by muse, mutect2
- TTC19 | c.19T>A p.W7R | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
